Somatic mutation profile of tumor specimen TCGA-AP-A0LL-01A (aliquot TCGA-AP-A0LL-01A-12D-A127-09) from TCGA case TCGA-AP-A0LL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 56.7 years (20,700 days).
Specimen TCGA-AP-A0LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3077bb98-7455-47d7-9741-9406c80ddab6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LL-10A (Blood Derived Normal), aliquot TCGA-AP-A0LL-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0f95456-0d3e-46b1-8161-d03837afad78

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Nonsense Mutation 4, In Frame Del 1, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 46/50 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- BRCA2 | c.5645C>A p.S1882* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as rs80358785, CM056302, CM980241, COSV101203821, COSV66450717; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5197G>T p.E1733* | Nonsense Mutation (SNP) | VAF 59/148 reads (40%) | catalogued as COSV61373497; called by muse, mutect2, varscan2
- ATG14 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 164/179 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55955864; called by muse, mutect2, varscan2
- ATP1A2 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63402921; called by muse, mutect2, varscan2
- ATP2B3 | c.3365G>A p.R1122H (on ENST00000263519 / NM_001001344.2; = p.P1173= on NM_021949.3) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs142573189, COSV54842847; called by muse, mutect2, varscan2
- CCDC158 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 213/501 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52953580; called by muse, mutect2, varscan2
- CELSR2 | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs747908171, COSV54768675; called by muse, mutect2, varscan2
- CSRNP1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377641112; called by muse, mutect2, varscan2
- FBN2 | c.2885T>C p.F962S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52500641; called by muse, mutect2, varscan2
- FBXO8 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1305491852, COSV67031136; called by muse, mutect2, varscan2
- FXR1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1184820013, COSV59761750; called by muse, mutect2, varscan2
- GALNT17 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); catalogued as rs1400903913, COSV61147106, COSV61164664; called by muse, mutect2, varscan2
- GK | c.1495G>A p.A499T (on ENST00000427190 / NM_001205019.2; = p.A493T on NM_000167.6) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66732115; called by muse, mutect2, varscan2
- GPR31 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as rs369377204; called by muse, mutect2, varscan2
- INTS9 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV68433554; called by muse, mutect2, varscan2
- KLHL12 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63042661; called by muse, mutect2, varscan2
- KLK7 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV58344045; called by muse, mutect2, varscan2
- LRRC71 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 198/260 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs569075318, COSV61656084; called by muse, mutect2, varscan2
- MED13L | c.4102C>T p.R1368W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56117470; called by muse, mutect2, varscan2
- MTOR | c.7534G>T p.D2512Y | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63868574, COSV63869433; called by muse, mutect2, varscan2
- MTUS1 | c.3394C>T p.Q1132* (on ENST00000262102 / NM_001363061.1; = p.Q298* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 97/225 reads (43%) | catalogued as COSV50552475; called by muse, mutect2, varscan2
- NFATC3 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as rs762594399, COSV60472051; called by muse, mutect2, varscan2
- OR4K14 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59292424; called by muse, mutect2, varscan2
- PRPS1L1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs374525106; called by muse, mutect2
- PXDNL | c.3108C>A p.Y1036* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV62482862; called by muse, mutect2, varscan2
- RBMS2 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56263257; called by muse, mutect2, varscan2
- SGK1 | c.1100_1102del p.K367del | In Frame Del (DEL) | VAF 52/144 reads (36%) | catalogued as rs1562235584; called by pindel, varscan2
- SH3BP5L | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 120/179 reads (67%) | SIFT tolerated (0.53); PolyPhen benign (0.08); catalogued as COSV63538950; called by muse, mutect2, varscan2
- SIGLEC14 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as COSV55777731, COSV99707845; called by muse, mutect2, varscan2
- SKOR1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58244651; called by muse, mutect2, varscan2
- SMC6 | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.221); catalogued as COSV61172376; called by muse, mutect2, varscan2
- SVEP1 | c.5881G>A p.V1961I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs748694581, COSV52837043; called by muse, mutect2
- TECPR1 | c.3160A>G p.N1054D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65782865; called by muse, mutect2, varscan2
- TRAPPC9 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758405220, COSV66895078; called by muse, mutect2, varscan2
- VWA8 | c.3454G>T p.D1152Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64994766; called by muse, mutect2, varscan2
- XRN2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs773271795, COSV65868798; called by muse, mutect2, varscan2
- ZFYVE28 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52108993; called by muse, mutect2, varscan2
- CTCF | c.1845dup p.E616* | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- SMG1 | c.9035_9051del p.N3012Rfs*13 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- APOBR | c.3234G>T p.L1078= (on ENST00000431282; = p.L1087= on NM_018690.4) | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- CSTF3 | c.738T>G p.A246= | Silent (SNP) | VAF 79/188 reads (42%) | catalogued as COSV60610179; called by muse, mutect2, varscan2
- HPSE | c.720G>A p.S240= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as rs150778862; called by muse, mutect2, varscan2
- IPO5 | c.2550C>T p.F850= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as COSV55152983; called by muse, mutect2, varscan2
- OR6C1 | c.631T>C p.L211= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs1295878804, COSV65572985; called by muse, mutect2, varscan2
- PTGER3 | c.1038C>T p.Y346= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV60689226; called by muse, mutect2, varscan2
- SMG5 | c.2991C>T p.H997= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs1485992877, COSV52744571; called by muse, mutect2, varscan2
- WDFY1 | c.642C>G p.L214= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV51788496, COSV99239997; called by muse, mutect2, varscan2
- ZNF148 | c.546G>A p.T182= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs772659045, COSV62302930; called by muse, mutect2, varscan2
- HERC2P3 | n.2328G>A | RNA (SNP) | VAF 25/135 reads (19%) | catalogued as rs187377229; called by muse, mutect2
